Somatic mutation profile of tumor specimen C3N-02424-01 (aliquot CPT0147080010) from CPTAC case C3N-02424, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-02424-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6031e4b0-fcfa-4cce-ad92-2f19c302f77d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02424-71 (Blood Derived Normal), aliquot CPT0147110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cf7698c-7e24-4e1a-9ccc-52db8cf51468

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Intron 6, 5'UTR 3, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, 5'Flank 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34B | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258467142; called by muse, mutect2
- ARHGEF16 | c.121T>A p.S41T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65681241; called by muse, mutect2, varscan2
- CDH12 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as COSV66405534; called by muse, mutect2
- CFAP53 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV68351359; called by muse, mutect2
- DUSP11 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 16/269 reads (6%) | catalogued as rs764581635; called by muse, mutect2
- EVX1 | c.423C>G p.S141R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV56086071; called by muse, mutect2
- FGB | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.225); catalogued as COSV57418577; called by muse, mutect2
- GABRB3 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.045); catalogued as rs777263662, COSV100160347; called by muse, mutect2
- HPD | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs762065329, COSV56641348; called by muse, mutect2, varscan2
- INPP5E | c.1901G>T p.S634I | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100867222; called by muse, mutect2, varscan2
- MAGEA4 | c.40del p.E14Kfs*137 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as COSV52340370; called by mutect2, pindel, varscan2
- MMP3 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 155/275 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100242924; called by muse, mutect2, varscan2
- NFASC | c.2705C>T p.A902V (on ENST00000339876 / NM_001378329.1; = p.A1005V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as rs761496452; called by muse, mutect2
- NXPE4 | c.1553T>C p.I518T (on ENST00000375478 / NM_001077639.2; = p.I234T on NM_017678.3) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs769310608; called by muse, mutect2, varscan2
- OR4N2 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 21/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60055551; called by muse, mutect2
- PREX2 | c.3070G>T p.D1024Y | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55761399, COSV55764900; called by muse, mutect2
- RNF213 | c.1426G>C p.V476L | Missense Mutation (SNP) | VAF 20/437 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV60623224; called by muse, mutect2
- SEMA3A | c.1658C>G p.T553R | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV99545672; called by muse, mutect2
- SGSH | c.25T>A p.C9S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs1400013703; called by muse, mutect2
- SLITRK3 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as rs1175446803; called by muse, mutect2
- ADAMTS9 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ADGRL3 | c.3047A>G p.H1016R (on ENST00000506720 / NM_001322402.2; = p.H948R on NM_015236.6) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGAP30 | c.2848C>A p.P950T (on ENST00000368013 / NM_001025598.2; = p.P739T on NM_181720.3) | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BMP2 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BMP2 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); called by muse, varscan2
- CDHR5 | c.618G>A p.R206= | Splice Region (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- CLCA2 | c.1986T>A p.G662= | Splice Region (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- CRTAC1 | c.253T>A p.Y85N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DLX6 | c.33G>C p.L11F | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH11 | c.10552C>T p.H3518Y | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- FAHD2B | c.861G>T p.R287S | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- FLG | c.6102T>A p.S2034R | Missense Mutation (SNP) | VAF 72/751 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- GLIPR2 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2, varscan2
- IGKV3-15 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- KCNA4 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.07); called by muse, mutect2
- KRT85 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 79/535 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- LHX8 | c.536dup p.L179Ffs*13 | Frame Shift Ins (INS) | VAF 22/188 reads (12%) | called by mutect2, pindel
- MALRD1 | c.5452G>T p.D1818Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MMP10 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MYT1L | c.258del p.V87Wfs*87 | Frame Shift Del (DEL) | VAF 33/306 reads (11%) | called by mutect2, pindel, varscan2
- OR2W3 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDE6A | c.23A>T p.E8V | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.1886A>T p.Y629F | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SALL1 | c.1754C>A p.T585N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SCIN | c.1647T>G p.S549R (on ENST00000297029 / NM_001112706.3; = p.S302R on NM_033128.3) | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SERPINA4 | c.436A>C p.S146R | Missense Mutation (SNP) | VAF 24/494 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.123); called by muse, mutect2
- SHROOM3 | c.3828-2A>T p.X1276_splice | Splice Site (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1710G>T p.R570S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- STOML2 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2
- TLN2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM32 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.734); called by muse, mutect2
- TSHR | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBE2QL1 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- UGT2A1 | c.1435C>A p.H479N | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- USP24 | c.7192C>G p.L2398V | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.067); called by muse, mutect2
- ZNF716 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- AHNAK | c.351A>G p.P117= | Silent (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- DDX11 | c.615T>C p.D205= | Silent (SNP) | VAF 53/416 reads (13%) | called by muse, mutect2, varscan2
- DRG2 | c.672C>G p.S224= | Silent (SNP) | VAF 17/237 reads (7%) | called by muse, mutect2
- EVC | c.2235G>A p.G745= | Silent (SNP) | VAF 20/235 reads (9%) | called by muse, mutect2
- FERMT3 | c.66G>A p.V22= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV99656719; called by muse, mutect2, varscan2
- FZD7 | c.1260G>T p.A420= | Silent (SNP) | VAF 12/267 reads (4%) | called by muse, mutect2
- LCT | c.4740T>C p.H1580= | Silent (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
- MYH11 | c.753C>T p.D251= | Silent (SNP) | VAF 17/573 reads (3%) | catalogued as rs775577319; called by muse, mutect2
- NPTN | c.768T>C p.T256= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- PDE3A | c.267G>A p.L89= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- SLC12A1 | c.567G>A p.L189= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV57708485; called by muse, mutect2
- TNXB | c.2022C>A p.G674= | Silent (SNP) | VAF 62/290 reads (21%) | catalogued as rs553907333; called by muse, mutect2, varscan2
- CFHR5 | c.-39T>C | 5'UTR (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- DPP10 | c.61-147064C>T | Intron (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- DROSHA | c.*86A>C | 3'UTR (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- FADD | c.-3G>A | 5'UTR (SNP) | VAF 40/464 reads (9%) | catalogued as rs373878223; called by muse, mutect2
- JMJD4 | c.693-16G>T | Intron (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- KCNA5 | c.-51G>A | 5'UTR (SNP) | VAF 17/124 reads (14%) | catalogued as rs1054827053; called by muse, mutect2, varscan2
- LMNA | c.357-3854A>T | Intron (SNP) | VAF 11/235 reads (5%) | called by muse, mutect2
- PHOSPHO1 | c.46-709G>A | Intron (SNP) | VAF 13/122 reads (11%) | catalogued as rs544058380; called by muse, mutect2, varscan2
- PPCS | chr1:42456043 del A | 5'Flank (DEL) | VAF 17/161 reads (11%) | called by mutect2, pindel, varscan2
- SCFD1 | c.855+4520G>A | Intron (SNP) | VAF 26/234 reads (11%) | called by muse, mutect2, varscan2
- TEX49 | c.79+8574del | Intron (DEL) | VAF 14/130 reads (11%) | called by mutect2, pindel, varscan2
